Somatic mutation profile of tumor specimen TARGET-10-PASINX-09A (aliquot TARGET-10-PASINX-09A-01D) from TARGET case TARGET-10-PASINX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.4 years (4,148 days).
Specimen TARGET-10-PASINX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6111d923-4a9e-4ee4-b050-17dabf8ef204.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASINX-10A (Blood Derived Normal), aliquot TARGET-10-PASINX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/972d8f1b-9c48-46a5-8aa0-65d2859a5142

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, Frame Shift Ins 2, Silent 2, Nonsense Mutation 1, Splice Site 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CD | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.26); PolyPhen possibly damaging (0.88); catalogued as rs587777390, CM143040, COSV63128879; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CD | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs397518423, CM067447, COSV63126880; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKT1 | c.236_237dup p.W80Sfs*67 | Frame Shift Ins (INS) | VAF 13/25 reads (52%) | catalogued as COSV62573489; called by mutect2, pindel*, varscan2*
- ALOX12 | c.1618C>T p.H540Y | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52349991; called by muse, mutect2, varscan2
- CNOT3 | c.732dup p.S245Qfs*8 | Frame Shift Ins (INS) | VAF 12/29 reads (41%) | catalogued as rs753475896; called by mutect2, varscan2
- FAM71E1 | c.415C>T p.R139W (on ENST00000600100 / NM_001308429.2; = p.R123W on NM_138411.3) | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs895120268, COSV58542313; called by muse, mutect2, varscan2
- KSR2 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56672921; called by muse, mutect2, varscan2
- NOTCH1 | c.7507C>T p.Q2503* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV53031077; called by muse, mutect2, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, mutect2, varscan2
- OR1C1 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs770848084, COSV68715741; called by muse, mutect2, varscan2
- PCLO | c.3332C>T p.T1111I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61635989; called by muse, mutect2, varscan2
- TENM3 | c.5533G>A p.G1845R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.069); catalogued as rs749252997, COSV69300041; called by muse, mutect2, varscan2
- HERPUD1 | c.611_612insGTCCCT p.I204delinsMSL | In Frame Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- KCNA5 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2
- UPF2 | c.2067+1G>T p.X689_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- MYH4 | c.4137C>T p.Y1379= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs375911403, COSV55114731; called by muse, mutect2, varscan2
- NOTCH3 | c.2493G>A p.G831= | Silent (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- CCDC88B | c.4375+31T>G | Intron (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- KCTD15 | c.693+111G>A | Intron (SNP) | VAF 15/27 reads (56%) | catalogued as rs769927300; called by muse, mutect2, varscan2
- PHBP20 | n.808C>A | RNA (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
